Somatic mutation profile of tumor specimen TCGA-DB-5270-01A (aliquot TCGA-DB-5270-01A-02D-1468-08) from TCGA case TCGA-DB-5270, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 38.1 years (13,904 days).
Specimen TCGA-DB-5270-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d6d6ea1-e08c-4719-88e6-4fa82bcf0c8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-5270-10A (Blood Derived Normal), aliquot TCGA-DB-5270-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28cbdec9-a9fe-41e4-b07e-8a30a5fe6899

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Nonsense Mutation 1, Frame Shift Del 1, Splice Region 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 34/111 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CAPRIN2 | c.2920A>C p.N974H | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99195435; called by muse, mutect2, varscan2
- EIF4G3 | c.3946A>G p.I1316V | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.462); catalogued as COSV99943540; called by muse, mutect2, varscan2
- FOXA3 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs200491833, COSV56215585; called by muse, mutect2, varscan2
- GRHL3 | c.307C>A p.L103I (on ENST00000350501 / NM_198174.3; = p.L108I on NM_021180.3) | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV99359112; called by muse, mutect2
- HDAC4 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV100612846; called by muse, varscan2
- MMP12 | c.125G>A p.G42D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.027); catalogued as rs782451057, COSV100404841; called by muse, mutect2, varscan2
- MUC16 | c.34910G>T p.S11637I | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV101198641; called by muse, mutect2, varscan2
- NEO1 | c.3651G>A p.G1217= | Splice Region (SNP) | VAF 12/52 reads (23%) | catalogued as rs150727403; called by muse, mutect2, varscan2
- OR5J2 | c.51G>C p.L17F | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); catalogued as COSV100398927; called by muse, varscan2
- RASA1 | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99169650; called by muse, mutect2, varscan2
- SLC24A3 | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV100039988; called by muse, mutect2, varscan2
- TBC1D15 | c.1846A>T p.K616* | Nonsense Mutation (SNP) | VAF 29/167 reads (17%) | catalogued as COSV100041469; called by muse, mutect2, varscan2
- ZNF875 | c.1531A>T p.T511S | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.089); catalogued as COSV100183128; called by muse, mutect2
- ATRX | c.1376dup p.S460Vfs*4 | Frame Shift Ins (INS) | VAF 97/438 reads (22%) | called by mutect2, pindel, varscan2
- TCF12 | c.874_878del p.P292Nfs*44 | Frame Shift Del (DEL) | VAF 19/104 reads (18%) | called by mutect2, pindel, varscan2
- HYDIN | c.2124G>C p.G708= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV99862284; called by muse, mutect2, varscan2
- LEF1 | c.735T>C p.H245= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV99489360; called by muse, mutect2, varscan2
- NUDT11 | c.444C>A p.S148= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV101047010; called by muse, mutect2, varscan2
- PCSK2 | c.1860G>A p.E620= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99358952; called by muse, mutect2, varscan2
- RTN4R | c.1074G>A p.A358= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs910459802, COSV99244872; called by muse, mutect2, varscan2
- DEPDC5 | c.*560C>T | 3'UTR (SNP) | VAF 40/185 reads (22%) | catalogued as rs755837385, COSV56710397; ClinVar: uncertain significance; called by muse, mutect2, varscan2
